Somatic mutation profile of tumor specimen CDDP-ABJ9-TTP1-A (aliquot CDDP-ABJ9-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABJ9, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 57 years.
Specimen CDDP-ABJ9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 302df732-8231-4ed6-bc05-7438a1ea2b03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABJ9-NB1-A (Blood Derived Normal), aliquot CDDP-ABJ9-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d605a1e2-3ee6-4b4c-bf57-89bd9564c408

The open-access MAF lists 736 somatic variants for this specimen: 505 protein-altering or splice-affecting, 147 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 420, Silent 147, Nonsense Mutation 37, Intron 35, RNA 21, Splice Site 17, Frame Shift Del 17, 3'UTR 13, Splice Region 9, 5'Flank 7, 5'UTR 7, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 190/624 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs199474729, CM020462, CM1311449, COSV62196329, COSV62207175; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.725G>C p.C242S | Missense Mutation (SNP) | VAF 284/544 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; called by muse, mutect2, varscan2
- TRPS1 | c.2723G>C p.R908P (on ENST00000220888 / NM_001330599.2; = p.R921P on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 238/1095 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908435, CM010486, CM010487, COSV55230612; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4002C>A p.N1334K (on ENST00000272895 / NM_173076.3; = p.N1016K on NM_015657.3) | Missense Mutation (SNP) | VAF 279/603 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.031); catalogued as COSV55952226; called by muse, mutect2, varscan2
- ABCA5 | c.3981G>C p.E1327D | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67019248; called by muse, mutect2
- ABCC11 | c.3432G>T p.Q1144H | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV62321836; called by muse, mutect2, varscan2
- ABI2 | c.233T>A p.I78N | Missense Mutation (SNP) | VAF 141/281 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53690441; called by muse, mutect2, varscan2
- ACAD10 | c.1913C>G p.S638C | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV100564268; called by muse, mutect2
- ACSBG1 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 101/234 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs544201014, COSV51904123; called by muse, mutect2, varscan2
- ACSM4 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 150/292 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748592689, COSV101257385, COSV68067084; called by muse, varscan2
- ADAMTS2 | c.2486C>A p.S829* | Nonsense Mutation (SNP) | VAF 82/1474 reads (6%) | catalogued as COSV52370863, COSV52383930; called by muse, mutect2
- ADAMTSL1 | c.4830G>T p.W1610C | Missense Mutation (SNP) | VAF 249/467 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65877080; called by muse, mutect2, varscan2
- ADGRF3 | c.2347C>A p.L783M (on ENST00000311519 / NM_001145168.1; = p.L584M on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 491/957 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV61049207, COSV61050448; called by muse, mutect2, varscan2
- AGTPBP1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV61269610; called by muse, varscan2
- AHRR | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 192/1099 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772512231, COSV57083815; called by muse, varscan2
- AIM2 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 103/360 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV63698810; called by muse, mutect2, varscan2
- AKAP9 | c.2785G>C p.E929Q | Missense Mutation (SNP) | VAF 40/742 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV100662888; called by muse, mutect2
- ALDH16A1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs780680412; called by muse, mutect2, varscan2
- ALPL | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 116/310 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.071); catalogued as CM021936, COSV66379552; called by muse, mutect2, varscan2
- ANAPC13 | c.23A>G p.D8G | Missense Mutation (SNP) | VAF 52/474 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as COSV59674930; called by muse, mutect2, varscan2
- ANGPT4 | c.1293C>A p.S431R | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317672169; called by muse, mutect2, varscan2
- ANK1 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 133/855 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55876337; called by muse, mutect2, varscan2
- ANKRD33B | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1275025696, COSV56976991; called by muse, mutect2
- ANKRD55 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV100591717; called by muse, mutect2, varscan2
- AP002512.3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs199694619, COSV54405850; called by muse, mutect2, varscan2
- ARHGEF17 | c.4372G>C p.A1458P | Missense Mutation (SNP) | VAF 186/475 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV55230416, COSV55230686; called by muse, mutect2, varscan2
- ATP7B | c.1016G>T p.R339M | Missense Mutation (SNP) | VAF 209/528 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV54436214, COSV99666538; called by muse, mutect2, varscan2
- ATR | c.2840C>T p.T947I | Missense Mutation (SNP) | VAF 89/464 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs771445846, COSV63384903; called by muse, varscan2
- B4GALNT1 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 263/550 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57541947; called by muse, mutect2, varscan2
- BAG3 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 286/684 reads (42%) | catalogued as COSV64841756; called by muse, mutect2, varscan2
- BAZ2A | c.4959C>G p.S1653R | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51633392; called by muse, mutect2, varscan2
- BMPR1B | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369168607; called by muse, mutect2
- BOC | c.1008G>C p.W336C | Missense Mutation (SNP) | VAF 48/283 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV56348290; called by muse, mutect2, varscan2
- BOD1L1 | c.8985G>T p.E2995D | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV50008041; called by muse, mutect2, varscan2
- BPIFB6 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 52/410 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as rs373792246; called by muse, mutect2, varscan2
- BRCA1 | c.5002T>C p.F1668L | Missense Mutation (SNP) | VAF 47/632 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs587781472; called by muse, mutect2
- BRINP1 | c.960C>A p.N320K | Missense Mutation (SNP) | VAF 183/567 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV56294633; called by muse, mutect2, varscan2
- BTBD16 | c.1053G>T p.W351C | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53261475; called by muse, mutect2, varscan2
- BTLA | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 158/307 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV57937686; called by muse, mutect2, varscan2
- BUD23 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 91/364 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs577588325, COSV56094397; called by muse, mutect2, varscan2
- C1orf158 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 156/605 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55346361; called by muse, mutect2, varscan2
- C2orf16 | c.1549C>A p.P517T | Missense Mutation (SNP) | VAF 202/458 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV62674308; called by muse, mutect2, varscan2
- CACNA1B | c.3521G>A p.R1174H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs200292544, COSV53117862; called by muse, mutect2
- CACNA1S | c.2315C>A p.P772H | Missense Mutation (SNP) | VAF 286/823 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1380941802, COSV62937395; called by muse, mutect2, varscan2
- CACNA1S | c.399G>T p.G133= | Splice Region (SNP) | VAF 210/569 reads (37%) | catalogued as COSV62937403; called by muse, mutect2, varscan2
- CARD11 | c.2795G>C p.R932P | Missense Mutation (SNP) | VAF 96/377 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs752709289, COSV62754385, COSV62754470, COSV62755617; called by muse, mutect2, varscan2
- CASKIN1 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58213195; called by muse, mutect2, varscan2
- CBLN2 | c.463A>G p.R155G | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.378); catalogued as COSV54050557; called by muse, mutect2, varscan2
- CCDC71 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 57/544 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV58909901; called by muse, mutect2, varscan2
- CCR2 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 112/784 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.898); catalogued as COSV52747951; called by muse, mutect2, varscan2
- CD163L1 | c.1087G>T p.D363Y | Missense Mutation (SNP) | VAF 135/301 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV58012664; called by muse, mutect2, varscan2
- CD1C | c.888G>T p.W296C | Missense Mutation (SNP) | VAF 156/368 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63805930; called by muse, mutect2, varscan2
- CD2 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 78/840 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs145678592; called by muse, mutect2
- CD79B | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 181/1122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1277301487, COSV50076369; called by muse, mutect2, varscan2
- CDH2 | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52274288; called by muse, mutect2, varscan2
- CDH20 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 217/687 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV53006288; called by muse, mutect2, varscan2
- CDH6 | c.1914del p.Q639Sfs*7 | Frame Shift Del (DEL) | VAF 69/480 reads (14%) | catalogued as COSV54072971, COSV54076964; called by mutect2, pindel, varscan2
- CDH8 | c.881C>A p.A294E | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1242043001, COSV54854584; called by muse, mutect2, varscan2
- CDK5RAP1 | c.920G>T p.G307V (on ENST00000357886 / NM_001365728.1; = p.G293V on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 338/513 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59426219; called by muse, mutect2, varscan2
- CEACAM18 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 94/397 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV67282391; called by muse, mutect2, varscan2
- CEACAM21 | c.835C>T p.P279S (on ENST00000401445 / NM_001098506.4; = p.P278S on NM_033543.6) | Missense Mutation (SNP) | VAF 141/353 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV51813281; called by muse, mutect2, varscan2
- CFHR4 | c.942G>T p.W314C (on ENST00000367416 / NM_001201551.2; = p.W315C on NM_001201550.3) | Missense Mutation (SNP) | VAF 147/461 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV52226065, COSV52232086; called by muse, mutect2, varscan2
- CFHR5 | c.445G>C p.V149L | Missense Mutation (SNP) | VAF 210/590 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.022); catalogued as COSV56819340; called by muse, mutect2, varscan2
- CHD5 | c.4475G>C p.R1492P | Missense Mutation (SNP) | VAF 116/382 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52410025, COSV99314497; called by muse, mutect2, varscan2
- CHL1 | c.197C>G p.T66R | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.197); catalogued as COSV56588840; called by muse, mutect2
- CIT | c.5053G>T p.V1685F | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55859238; called by muse, mutect2, varscan2
- CNPY3 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs375246952; called by muse, mutect2
- COL16A1 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as COSV54702116; called by muse, mutect2, varscan2
- COL7A1 | c.5737G>C p.G1913R | Missense Mutation (SNP) | VAF 354/717 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM093147, COSV60392488; called by muse, mutect2, varscan2
- COQ10B | c.641G>T p.R214I | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs956383213, COSV55836032; called by muse, mutect2, varscan2
- CP | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 184/909 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52829591; called by muse, mutect2, varscan2
- CPA3 | c.898T>C p.Y300H | Missense Mutation (SNP) | VAF 71/670 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV56044202; called by muse, mutect2, varscan2
- CPN2 | c.1346G>T p.R449L | Missense Mutation (SNP) | VAF 179/781 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV60469805, COSV60471302; called by muse, mutect2, varscan2
- CRB1 | c.2073G>T p.W691C | Missense Mutation (SNP) | VAF 215/490 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66329059; called by muse, mutect2, varscan2
- CREBBP | c.2468A>T p.Q823L | Missense Mutation (SNP) | VAF 272/557 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV52117087, COSV99273493; called by muse, mutect2, varscan2
- CSMD3 | c.7321G>T p.E2441* (on ENST00000297405 / NM_001363185.1; = p.E2337* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 255/523 reads (49%) | catalogued as COSV52128371, COSV52178743; called by muse, mutect2, varscan2
- CSPP1 | c.2934C>G p.I978M (on ENST00000676605; = p.I937M on NM_024790.6) | Missense Mutation (SNP) | VAF 30/441 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV51592761; called by muse, mutect2
- CSRNP3 | c.232A>G p.R78G | Missense Mutation (SNP) | VAF 72/792 reads (9%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); catalogued as rs370657022; called by muse, mutect2
- CWH43 | c.1498C>A p.H500N | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV56936183, COSV56936996; called by muse, mutect2, varscan2
- CYGB | c.572A>C p.*191Sext*3 | Nonstop Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV53149859; called by muse, varscan2
- CYP4F22 | c.845G>T p.R282L | Missense Mutation (SNP) | VAF 129/530 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54107193; called by muse, mutect2, varscan2
- DACH2 | c.792G>T p.W264C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV64190917; called by muse, mutect2, varscan2
- DCC | c.1925G>T p.S642I | Missense Mutation (SNP) | VAF 143/553 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV59090762; called by muse, mutect2, varscan2
- DDX3X | c.1567G>A p.E523K (on ENST00000399959; = p.E524K on NM_001356.5) | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67863234; called by muse, mutect2, varscan2
- DHRS3 | c.505C>A p.H169N | Missense Mutation (SNP) | VAF 189/538 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66107764; called by muse, mutect2, varscan2
- DNAH3 | c.9703C>A p.L3235I | Missense Mutation (SNP) | VAF 269/521 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54509716; called by muse, mutect2, varscan2
- DOCK10 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV51358632; called by muse, mutect2
- DPP10 | c.1314-1G>T p.X438_splice | Splice Site (SNP) | VAF 16/157 reads (10%) | catalogued as COSV59672139; called by muse, mutect2, varscan2
- DPP10 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100059224, COSV59672496; called by muse, mutect2
- DSC1 | c.1402G>T p.G468C | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527601806, COSV57142987; called by mutect2, varscan2
- DSG4 | c.1450T>C p.C484R | Missense Mutation (SNP) | VAF 144/591 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as COSV57389238; called by muse, mutect2, varscan2
- DST | c.5144C>G p.S1715C | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV55004811; called by muse, mutect2
- DYNC2H1 | c.9893C>T p.S3298L | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV62104219; called by muse, mutect2
- DYRK2 | c.1417G>T p.G473C (on ENST00000344096 / NM_006482.3; = p.G400C on NM_003583.4) | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59845654; called by muse, mutect2, varscan2
- ELFN1 | c.422C>A p.A141D | Missense Mutation (SNP) | VAF 138/384 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV70033986; called by muse, mutect2, varscan2
- ENHO | c.102C>A p.C34* | Nonsense Mutation (SNP) | VAF 251/459 reads (55%) | catalogued as COSV54279462; called by muse, mutect2, varscan2
- ENPEP | c.345C>A p.Y115* | Nonsense Mutation (SNP) | VAF 270/1094 reads (25%) | catalogued as COSV54448113; called by muse, mutect2, varscan2
- EPHA6 | c.2413G>T p.A805S (on ENST00000389672 / NM_001080448.3; = p.A197S on NM_173655.4) | Missense Mutation (SNP) | VAF 214/468 reads (46%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.007); catalogued as COSV67563666; called by muse, mutect2, varscan2
- EPHA8 | c.1954G>C p.G652R | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779031605, COSV51264339; called by muse, mutect2, varscan2
- ERBB4 | c.2435A>C p.K812T | Missense Mutation (SNP) | VAF 288/667 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV61473143, COSV61517079; called by muse, mutect2, varscan2
- ESF1 | c.913G>C p.G305R | Missense Mutation (SNP) | VAF 74/411 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52519628, COSV99176533; called by muse, mutect2, varscan2
- ETV6 | c.873G>T p.R291S | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs763478533, COSV67148654; called by muse, mutect2
- EXOC5 | c.568C>G p.H190D | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.437); catalogued as COSV61770355; called by muse, mutect2, varscan2
- EYA1 | c.426G>T p.L142F | Missense Mutation (SNP) | VAF 380/1121 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100378906, COSV58158809; called by muse, mutect2, varscan2
- F12 | c.676C>G p.R226G | Missense Mutation (SNP) | VAF 199/797 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53690337, COSV53692278; called by muse, mutect2, varscan2
- F7 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 248/642 reads (39%) | catalogued as COSV60645429; called by muse, mutect2, varscan2
- FAM135B | c.404G>A p.S135N | Missense Mutation (SNP) | VAF 90/419 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV50523480; called by muse, mutect2, varscan2
- FAM71B | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 111/355 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57228036; called by muse, mutect2, varscan2
- FCRL5 | c.1819C>A p.L607M | Missense Mutation (SNP) | VAF 101/444 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62511647; called by muse, mutect2, varscan2
- FGG | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV60194782; called by muse, mutect2, varscan2
- FILIP1 | c.3098G>A p.G1033E | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV52724828; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 83/276 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs139756425, COSV52545859; called by muse, mutect2, varscan2
- FOXP2 | c.992C>A p.S331* | Nonsense Mutation (SNP) | VAF 70/443 reads (16%) | catalogued as COSV63483266, COSV63489074; called by muse, mutect2, varscan2
- FREM2 | c.3866A>G p.E1289G | Missense Mutation (SNP) | VAF 158/425 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV54831483; called by muse, mutect2, varscan2
- FRMPD4 | c.2884G>A p.G962S | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs144088214, COSV66212366; called by muse, mutect2, varscan2
- FSHR | c.1703C>A p.T568N | Missense Mutation (SNP) | VAF 203/386 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1168826778, COSV58619715; called by muse, mutect2, varscan2
- GABRA2 | c.1348A>T p.S450C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.334); catalogued as COSV62913034; called by muse, mutect2
- GLG1 | c.1784G>T p.C595F | Missense Mutation (SNP) | VAF 98/395 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52664697; called by muse, mutect2, varscan2
- GRB14 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV55736525; called by muse, varscan2
- GRIK5 | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.227); catalogued as COSV53476086; called by muse, mutect2, varscan2
- GSTM1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 59/441 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs781192005, COSV59166495; called by muse, mutect2, varscan2
- GUCY1A2 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 126/329 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.668); catalogued as COSV56480894; called by muse, mutect2, varscan2
- GUK1 | c.390G>T p.L130= | Splice Region (SNP) | VAF 144/457 reads (32%) | catalogued as COSV57155379; called by muse, mutect2, varscan2
- HACD1 | c.264G>T p.L88F | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs1554816828, COSV63515863, COSV63516129; called by muse, varscan2
- HECW2 | c.2361G>T p.Q787H | Missense Mutation (SNP) | VAF 181/378 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV53652583, COSV53671920; called by muse, mutect2, varscan2
- HEPACAM | c.674A>T p.Q225L | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as COSV53429087; called by muse, mutect2
- HGFAC | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs536514881, COSV66976714; called by muse, mutect2, varscan2
- HIRA | c.2297G>T p.R766L | Missense Mutation (SNP) | VAF 175/378 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV54273169; called by muse, mutect2, varscan2
- HLX | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV65044501; called by muse, mutect2, varscan2
- HRNR | c.2237C>G p.S746* | Nonsense Mutation (SNP) | VAF 70/1596 reads (4%) | catalogued as COSV64257634; called by muse, mutect2
- HSD3B2 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 226/514 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as rs1283501906, COSV65592771; called by muse, mutect2, varscan2
- ICE1 | c.5102C>G p.S1701C | Missense Mutation (SNP) | VAF 126/1201 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.245); catalogued as COSV56818951, COSV56821034; called by muse, mutect2, varscan2
- IFITM1 | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 62/411 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs759637364; called by muse, mutect2, varscan2
- IGSF1 | c.1459C>G p.R487G | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.349); catalogued as COSV63836609, COSV63839040; called by muse, mutect2, varscan2
- IKZF1 | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 210/796 reads (26%) | catalogued as COSV58782886; called by muse, mutect2, varscan2
- IL2 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 28/182 reads (15%) | catalogued as COSV56986056; called by muse, mutect2
- IL26 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV57488516; called by muse, mutect2
- ILF3 | c.2681G>T p.R894I | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV51555056; called by muse, mutect2, varscan2
- INSM1 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV59604572; called by muse, mutect2, varscan2
- ITGAM | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 202/316 reads (64%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV54935152; called by muse, varscan2
- ITIH1 | c.1053C>A p.N351K | Missense Mutation (SNP) | VAF 22/524 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1031953101; called by muse, mutect2
- ITIH5 | c.400G>T p.G134* | Nonsense Mutation (SNP) | VAF 73/293 reads (25%) | catalogued as COSV56900261; called by muse, mutect2, varscan2
- KANSL2 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778352224, COSV63479489; called by muse, varscan2
- KCNF1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs1230735235; called by muse, mutect2
- KCNH7 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 26/415 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59790106; called by muse, mutect2
- KCNQ2 | c.926C>G p.A309G | Missense Mutation (SNP) | VAF 46/972 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as CM135151; called by muse, mutect2
- KCNT1 | c.2506A>G p.M836V (on ENST00000488444; = p.M855V on NM_020822.3) | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs762496807; called by muse, mutect2, varscan2
- KDM6A | c.2062A>C p.N688H | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65038058; called by muse, mutect2, varscan2
- KEL | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 162/484 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs200557043, COSV62333899; called by muse, mutect2, varscan2
- KIAA0100 | c.2864G>A p.G955D | Missense Mutation (SNP) | VAF 131/455 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.05); catalogued as COSV66491227; called by muse, mutect2, varscan2
- KIAA1549 | c.2063C>A p.S688Y | Missense Mutation (SNP) | VAF 59/397 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV54308291; called by muse, mutect2, varscan2
- KIF14 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 27/754 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1211135514; called by muse, mutect2
- KIF21A | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62768565; called by muse, mutect2, varscan2
- KIF4B | c.3599C>T p.T1200I | Missense Mutation (SNP) | VAF 105/488 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.096); catalogued as COSV70528418; called by muse, mutect2, varscan2
- KIFBP | c.425A>G p.Q142R | Missense Mutation (SNP) | VAF 74/340 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1290898365; called by muse, mutect2, varscan2
- KIR3DX1 | n.1183-8C>T | Splice Region (SNP) | VAF 46/614 reads (7%) | catalogued as rs1469901359; called by muse, mutect2
- KRIT1 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 46/793 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as CM135503; called by muse, mutect2
- KRT2 | c.1303C>A p.L435I | Missense Mutation (SNP) | VAF 155/651 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as COSV59009522; called by muse, mutect2, varscan2
- LARS2 | c.*794G>T | Splice Region (SNP) | VAF 167/307 reads (54%) | catalogued as COSV55526048; called by muse, varscan2
- LAX1 | c.90A>G p.R30= | Splice Region (SNP) | VAF 113/561 reads (20%) | catalogued as COSV65848873; called by muse, mutect2, varscan2
- LGR5 | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200272164, COSV57003493; called by muse, varscan2
- LIMCH1 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 386/1108 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV58277080; called by muse, mutect2, varscan2
- LRFN5 | c.1151C>G p.T384R | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV53247446; called by muse, mutect2, varscan2
- LRP10 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.154); catalogued as COSV62077871; called by muse, mutect2, varscan2
- LRP1B | c.12845C>A p.P4282Q | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV67189674, COSV67216284; called by muse, mutect2, varscan2
- LRP1B | c.9460C>A p.H3154N | Missense Mutation (SNP) | VAF 203/442 reads (46%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.98); catalogued as COSV67232440; called by muse, varscan2
- LRP5 | c.4667G>A p.R1556H | Missense Mutation (SNP) | VAF 44/424 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs764447598, COSV53715147; called by muse, mutect2, varscan2
- LRRC37A2 | c.4810-7A>G | Splice Region (SNP) | VAF 68/604 reads (11%) | catalogued as rs775123324; called by muse, mutect2, varscan2
- LRRIQ1 | c.3719G>T p.S1240I | Missense Mutation (SNP) | VAF 247/1364 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV67827337; called by muse, mutect2, varscan2
- LZTR1 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 175/340 reads (51%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.994); catalogued as COSV53145935; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 86/512 reads (17%) | catalogued as COSV53798729; called by muse, mutect2, varscan2
- ME2 | c.199C>G p.R67G | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV58422569; called by muse, mutect2, varscan2
- MECOM | c.2200A>T p.T734S (on ENST00000468789 / NM_001105078.4; = p.T922S on NM_004991.4) | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV52961354, COSV99244232; called by muse, mutect2
- MED25 | c.570del p.L191Ffs*23 | Frame Shift Del (DEL) | VAF 49/385 reads (13%) | catalogued as COSV100457364, COSV57206218; called by mutect2, pindel, varscan2
- MGAM | c.3932G>C p.R1311P | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72073440, COSV72073989; called by muse, mutect2, varscan2
- MLLT6 | c.2008A>G p.M670V | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.174); catalogued as rs996058528; called by muse, mutect2, varscan2
- MORC2 | c.2915G>T p.R972L (on ENST00000397641 / NM_001303256.3; = p.R910L on NM_014941.3) | Missense Mutation (SNP) | VAF 172/612 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV53197063; called by muse, mutect2, varscan2
- MPND | c.760A>T p.T254S | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV53656239; called by muse, mutect2, varscan2
- MPST | c.362G>T p.G121V (on ENST00000341116 / NM_001369904.2; = p.G141V on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62017323; called by muse, mutect2, varscan2
- MROH7 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 252/454 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV59869138; called by muse, mutect2, varscan2
- MRTO4 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs750997503, COSV57673255; called by muse, mutect2, varscan2
- MSI1 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as rs1181920771; called by muse, mutect2, varscan2
- MST1R | c.3911G>T p.R1304L | Missense Mutation (SNP) | VAF 55/522 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs998378597, COSV56564990, COSV56565950; called by muse, mutect2, varscan2
- MTHFD1L | c.2568G>T p.Q856H | Missense Mutation (SNP) | VAF 141/245 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV66224286; called by muse, mutect2, varscan2
- MTMR12 | c.1008G>C p.Q336H | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53787458; called by muse, mutect2, varscan2
- MTRR | c.1227G>T p.K409N (on ENST00000264668; = p.K382N on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 613/1177 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52942295; called by muse, mutect2, varscan2
- MYH1 | c.4731T>A p.D1577E | Missense Mutation (SNP) | VAF 297/573 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0.075); catalogued as COSV56845093; called by muse, mutect2, varscan2
- MYOG | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 193/343 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as COSV54095180; called by muse, mutect2
- MYOM3 | c.4207G>A p.G1403S | Missense Mutation (SNP) | VAF 98/564 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773501383, COSV58391370, COSV58399053; called by muse, mutect2, varscan2
- NEIL1 | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 122/392 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61833167; called by muse, mutect2, varscan2
- NES | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 354/872 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV63960542; called by muse, mutect2, varscan2
- NEUROD4 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 58/287 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV54470896; called by muse, mutect2, varscan2
- NF1 | c.4431-1G>T p.X1477_splice (on ENST00000358273 / NM_001042492.3; = p.X1456_splice on NM_000267.3) | Splice Site (SNP) | VAF 198/622 reads (32%) | catalogued as CS000876, CS086423, COSV100646896, COSV62205691; called by muse, mutect2, varscan2
- NIPAL4 | c.923G>C p.G308A | Missense Mutation (SNP) | VAF 321/634 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV57424735; called by muse, mutect2, varscan2
- NR3C2 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 150/604 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as COSV60986907; called by muse, mutect2, varscan2
- NTRK1 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 99/258 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.127); catalogued as rs754611476, COSV62324015, COSV62325910; called by muse, mutect2, varscan2
- NUBPL | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 175/1076 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.288); catalogued as COSV55266396; called by muse, mutect2, varscan2
- NUP37 | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV51837249; called by muse, mutect2, varscan2
- OPA1 | c.131A>G p.H44R | Missense Mutation (SNP) | VAF 146/595 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.046); catalogued as rs1340467055, COSV62479424; called by muse, mutect2, varscan2
- OR10A5 | c.870C>G p.I290M | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV55053472; called by muse, mutect2, varscan2
- OR10G9 | c.719G>C p.C240S | Missense Mutation (SNP) | VAF 125/292 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV66685939; called by muse, varscan2
- OR11H2 | c.556G>T p.G186W (on ENST00000556246; = p.G197W on NM_001197287.1) | Missense Mutation (SNP) | VAF 149/1303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73703671; called by mutect2, varscan2
- OR13F1 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 131/586 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); catalogued as COSV58251087; called by muse, mutect2, varscan2
- OR2L2 | c.582T>A p.Y194* | Nonsense Mutation (SNP) | VAF 64/700 reads (9%) | catalogued as COSV63549702; called by muse, mutect2
- OR2M3 | c.74C>G p.T25S | Missense Mutation (SNP) | VAF 112/369 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV71758962; called by muse, mutect2, varscan2
- OR2W3 | c.924G>T p.K308N | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV64456307; called by muse, varscan2
- OR4A5 | c.754A>C p.I252L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as COSV60521941; called by muse, mutect2, varscan2
- OR4C15 | c.287T>A p.L96Q (on ENST00000314644; = p.L42Q on NM_001001920.2) | Missense Mutation (SNP) | VAF 63/465 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58951637; called by muse, mutect2, varscan2
- OR4C16 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as rs768088465, COSV58941161, COSV58942178; called by muse, mutect2, varscan2
- OR4D10 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 146/353 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs755747713, COSV73259988; called by muse, varscan2
- OR4S2 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56746170; called by muse, mutect2, varscan2
- OR4X2 | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.619); catalogued as COSV56582616; called by muse, mutect2, varscan2
- OR51F1 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 43/333 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV100598605; called by muse, mutect2, varscan2
- OR7G2 | c.247T>A p.F83I | Missense Mutation (SNP) | VAF 278/674 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59687497; called by muse, mutect2, varscan2
- OR8J1 | c.84C>G p.F28L | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57317058, COSV57317117; called by muse, mutect2, varscan2
- OSBPL11 | c.1372C>T p.H458Y | Missense Mutation (SNP) | VAF 101/848 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1381676309; called by muse, mutect2, varscan2
- OTOG | c.1126A>T p.S376C | Missense Mutation (SNP) | VAF 76/493 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68036815; called by muse, mutect2, varscan2
- OXCT2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.416); catalogued as rs1294767970; called by muse, mutect2, varscan2
- PAG1 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 39/574 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55056229, COSV55057204; called by muse, mutect2
- PAPOLB | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 48/524 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.152); catalogued as COSV68199863; called by muse, mutect2
- PAPPA2 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 171/736 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV62774852; called by muse, mutect2, varscan2
- PARP15 | c.1530G>T p.K510N (on ENST00000464300 / NM_001113523.3; = p.K276N on NM_152615.2) | Missense Mutation (SNP) | VAF 227/493 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.865); catalogued as COSV59971699; called by muse, mutect2, varscan2
- PAX6 | c.206G>T p.R69M | Missense Mutation (SNP) | VAF 336/833 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53792366, COSV53794262; called by muse, mutect2, varscan2
- PCDHGA4 | c.720C>G p.H240Q | Missense Mutation (SNP) | VAF 222/417 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.034); catalogued as COSV53914822, COSV53933452, COSV54015446; called by muse, mutect2, varscan2
- PCDHGA7 | c.2047G>T p.G683C | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as COSV53898828, COSV53914835; called by muse, mutect2, varscan2
- PCDHGB6 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 41/323 reads (13%) | catalogued as rs770899981; called by muse, mutect2, varscan2
- PKN1 | c.2482G>A p.V828I | Missense Mutation (SNP) | VAF 44/508 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as rs779590344; called by muse, mutect2
- PLBD1 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.186); catalogued as COSV53696285; called by muse, mutect2
- PLEC | c.9037G>A p.E3013K (on ENST00000322810 / NM_201380.4; = p.E2903K on NM_000445.5) | Missense Mutation (SNP) | VAF 40/610 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs782517831, COSV100508929; ClinVar: uncertain significance; called by muse, mutect2
- PLXNA3 | c.4631A>T p.Q1544L | Missense Mutation (SNP) | VAF 83/119 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as COSV63753463; called by muse, mutect2, varscan2
- PLXNB1 | c.3712G>T p.E1238* | Nonsense Mutation (SNP) | VAF 42/180 reads (23%) | catalogued as COSV56487704, COSV56495078; called by muse, mutect2, varscan2
- PLXND1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs942266675; called by muse, mutect2
- PML | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 68/572 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as COSV51443627; called by muse, mutect2, varscan2
- PMS2 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 216/708 reads (31%) | catalogued as COSV56220274, COSV99763748; called by muse, mutect2, varscan2
- POLN | c.2065G>T p.G689W | Missense Mutation (SNP) | VAF 189/534 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67023988; called by muse, mutect2, varscan2
- POTEE | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 316/694 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as COSV58236590; called by muse, mutect2, varscan2
- PRG4 | c.2720C>A p.T907N | Missense Mutation (SNP) | VAF 571/1527 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV63355102; called by muse, mutect2, varscan2
- PRKDC | c.11222G>T p.R3741L | Missense Mutation (SNP) | VAF 216/639 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs759518580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR27 | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); catalogued as COSV60640303; called by muse, varscan2
- PTGDS | c.59T>A p.L20Q | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV56399687; called by muse, mutect2, varscan2
- PTH2R | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV55914631; called by muse, mutect2, varscan2
- PTPRH | c.3200C>A p.A1067D | Missense Mutation (SNP) | VAF 85/386 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54743620; called by muse, mutect2, varscan2
- RAD54B | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV60250144; called by muse, mutect2
- RASA2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 167/375 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs1344227897, COSV53937233; called by muse, mutect2, varscan2
- RB1 | c.2325+1G>T p.X775_splice | Splice Site (SNP) | VAF 104/269 reads (39%) | catalogued as CS058012, COSV57302937, COSV57317467; called by muse, varscan2
- RBM6 | c.3104G>T p.R1035M | Missense Mutation (SNP) | VAF 203/393 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV56480606; called by muse, mutect2, varscan2
- RHBG | c.1064T>A p.L355Q | Missense Mutation (SNP) | VAF 72/430 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1310840857; called by muse, mutect2, varscan2
- RHOJ | c.497C>G p.A166G | Missense Mutation (SNP) | VAF 70/347 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV57456574, COSV57457254; called by muse, mutect2, varscan2
- RIOK3 | c.1396A>C p.N466H | Missense Mutation (SNP) | VAF 94/410 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as COSV59772405; called by muse, varscan2
- RIT2 | c.61T>A p.Y21N | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56295641; called by muse, mutect2, varscan2
- RNF10 | c.707A>G p.K236R | Missense Mutation (SNP) | VAF 112/297 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.182); catalogued as rs1307604150, COSV58044006; called by muse, mutect2, varscan2
- ROBO2 | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 19/282 reads (7%) | catalogued as COSV100165303; called by muse, mutect2
- RPE65 | c.1129-1G>T p.X377_splice | Splice Site (SNP) | VAF 121/773 reads (16%) | catalogued as COSV52014008; called by muse, mutect2, varscan2
- RPS4Y2 | c.164C>A p.A55E | Missense Mutation (SNP) | VAF 97/197 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56488102; called by muse, mutect2, varscan2
- RTP3 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV56123510, COSV56123645; called by muse, mutect2, varscan2
- RTTN | c.2121G>T p.L707F | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.246); catalogued as COSV55342518; called by muse, mutect2, varscan2
- RYR2 | c.8173G>T p.A2725S | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.973); catalogued as rs1295247163, COSV63670854; called by muse, mutect2
- RYR2 | c.12910G>T p.G4304C | Missense Mutation (SNP) | VAF 112/836 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV63670868; called by muse, mutect2, varscan2
- SASS6 | c.949G>C p.V317L | Missense Mutation (SNP) | VAF 67/488 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV54926949; called by muse, mutect2, varscan2
- SCN2A | c.1888C>A p.R630S | Missense Mutation (SNP) | VAF 169/347 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.175); catalogued as COSV51830631, COSV51835366; called by muse, mutect2, varscan2
- SCN9A | c.2479G>C p.D827H (on ENST00000303354; = p.D816H on NM_002977.3) | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV57603523; called by muse, mutect2
- SCNN1A | c.1792G>T p.G598W | Missense Mutation (SNP) | VAF 58/546 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57434662; called by muse, mutect2, varscan2
- SEMG2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 62/586 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.652); catalogued as COSV65647820; called by muse, varscan2
- SERINC2 | c.116G>A p.R39H (on ENST00000373709 / NM_178865.5; = p.R43H on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/320 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs946339787, COSV65489655; called by muse, varscan2
- SERPINB13 | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV54027789, COSV54028454; called by muse, mutect2, varscan2
- SIPA1L2 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 140/478 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs375148818; called by muse, mutect2, varscan2
- SIRPB2 | c.955G>C p.G319R | Missense Mutation (SNP) | VAF 79/481 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV63123275; called by muse, mutect2, varscan2
- SLC12A3 | c.626G>C p.R209P | Missense Mutation (SNP) | VAF 120/499 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758035631, CM014395, COSV52633181; called by muse, mutect2, varscan2
- SLC22A15 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 278/699 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV65677521; called by muse, mutect2, varscan2
- SLC22A16 | c.1061G>C p.S354T | Missense Mutation (SNP) | VAF 224/462 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV57927740, COSV57928125, COSV57932001; called by muse, mutect2, varscan2
- SLC22A18 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56539250; called by muse, mutect2, varscan2
- SLC22A23 | c.1372A>T p.K458* | Nonsense Mutation (SNP) | VAF 189/358 reads (53%) | catalogued as COSV66676908; called by muse, mutect2, varscan2
- SLC25A28 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 278/524 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV65125217; called by muse, mutect2, varscan2
- SLC26A7 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52588193, COSV99404483; called by muse, mutect2, varscan2
- SLC2A9 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 184/567 reads (32%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.991); catalogued as rs1163158259, COSV53317855; called by muse, varscan2
- SLC2A9 | c.1156G>C p.G386R | Missense Mutation (SNP) | VAF 184/566 reads (33%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV53317879; called by muse, varscan2
- SLC30A8 | c.95T>A p.V32E | Missense Mutation (SNP) | VAF 345/619 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV69968973; called by muse, mutect2, varscan2
- SLC35F5 | c.1022C>G p.A341G | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99830040; called by muse, mutect2
- SLC7A14 | c.582G>T p.L194F | Missense Mutation (SNP) | VAF 114/908 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV51579325, COSV99200376; called by muse, mutect2, varscan2
- SMARCAD1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 44/480 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV62772969; called by muse, mutect2
- SNX18 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.076); catalogued as COSV57988296; called by muse, mutect2, varscan2
- SRGAP3 | c.2758G>T p.A920S | Missense Mutation (SNP) | VAF 229/513 reads (45%) | SIFT tolerated, low confidence (0.44); PolyPhen probably damaging (0.964); catalogued as COSV64531393, COSV64535889; called by muse, mutect2, varscan2
- STX6 | c.461T>A p.F154Y | Missense Mutation (SNP) | VAF 147/489 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as COSV51111414; called by muse, mutect2, varscan2
- SUGP1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs376950672, COSV99894364; called by muse, mutect2, varscan2
- SUPT16H | c.1154A>G p.D385G | Missense Mutation (SNP) | VAF 101/540 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV53523028; called by muse, mutect2, varscan2
- TAF9 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 39/560 reads (7%) | catalogued as COSV54204638; called by muse, mutect2
- TAPBP | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV70457111; called by muse, varscan2
- TAPT1 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58823031; called by muse, mutect2
- TEAD1 | c.617G>T p.W206L | Missense Mutation (SNP) | VAF 106/826 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV57562463; called by muse, mutect2, varscan2
- TESK2 | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 94/427 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59150190; called by muse, mutect2, varscan2
- TGFB2 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 47/591 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV65108544; called by muse, mutect2
- TGM4 | c.242G>T p.R81M | Missense Mutation (SNP) | VAF 44/461 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as COSV56093163, COSV99066697; called by muse, mutect2
- TMEM132E | c.1528C>A p.Q510K (on ENST00000321639; = p.Q600K on NM_001304438.2) | Missense Mutation (SNP) | VAF 219/721 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV58695404; called by muse, mutect2, varscan2
- TMEM182 | c.511del p.V171Sfs*13 | Frame Shift Del (DEL) | VAF 32/269 reads (12%) | catalogued as COSV101305347; called by mutect2, pindel, varscan2
- TMEM8B | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.039); catalogued as rs778446612, COSV65075779; called by muse, mutect2
- TMTC4 | c.2059A>G p.S687G (on ENST00000376234 / NM_001350577.2; = p.S706G on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as COSV60891649; called by muse, mutect2, varscan2
- TNN | c.2924C>A p.P975H | Missense Mutation (SNP) | VAF 157/377 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1218269980, COSV53423099; called by muse, mutect2, varscan2
- TNNT3 | c.563A>T p.K188M (on ENST00000397301 / NM_001367846.1; = p.K177M on NM_006757.4) | Missense Mutation (SNP) | VAF 372/828 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs889645401, COSV53484484; called by muse, mutect2, varscan2
- TNR | c.3383-1G>T p.X1128_splice | Splice Site (SNP) | VAF 183/422 reads (43%) | catalogued as COSV54886002; called by muse, mutect2, varscan2
- TOPORS | c.2240G>T p.R747I | Missense Mutation (SNP) | VAF 268/496 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV62116424; called by muse, mutect2, varscan2
- TOR3A | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as COSV61679818; called by muse, mutect2, varscan2
- TRAPPC8 | c.958T>A p.S320T | Missense Mutation (SNP) | VAF 77/501 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV51968384; called by muse, mutect2, varscan2
- TRIM10 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 416/748 reads (56%) | catalogued as rs1201369706; called by muse, mutect2, varscan2
- TRIM55 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 108/683 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.42); catalogued as COSV52544457; called by muse, mutect2, varscan2
- TRIP11 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs1404122067, COSV50927213; called by muse, mutect2, varscan2
- TRO | c.3389G>A p.G1130D | Missense Mutation (SNP) | VAF 159/222 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.418); catalogued as rs1428135766, COSV51499119, COSV99435632; called by muse, mutect2, varscan2
- TRPC7 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 9/261 reads (3%) | catalogued as rs1176153805; called by muse, mutect2
- TSHR | c.909G>T p.E303D | Missense Mutation (SNP) | VAF 140/512 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV53315287, COSV53328790; called by muse, mutect2, varscan2
- TTI2 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 117/656 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); catalogued as rs759586004, COSV100659851, COSV62452216; called by muse, mutect2
- TTLL10 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs555277428; called by muse, mutect2, varscan2
- TUSC3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1335638161, COSV65877526, COSV65886386; called by muse, mutect2, varscan2
- TUT4 | c.109A>T p.R37* | Nonsense Mutation (SNP) | VAF 45/322 reads (14%) | catalogued as COSV57111213; called by muse, mutect2, varscan2
- TXLNA | c.377C>G p.T126S | Missense Mutation (SNP) | VAF 38/446 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV65313999; called by muse, mutect2
- UBAC1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 113/399 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.924); catalogued as COSV65613833; called by muse, mutect2, varscan2
- UBE3C | c.1453G>T p.G485C | Missense Mutation (SNP) | VAF 120/412 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61952035; called by muse, varscan2
- UBR2 | c.5119G>T p.G1707* | Nonsense Mutation (SNP) | VAF 171/314 reads (54%) | catalogued as COSV65749271, COSV65749992; called by muse, mutect2, varscan2
- UGT8 | c.712A>T p.S238C | Missense Mutation (SNP) | VAF 97/369 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV60416814; called by muse, mutect2, varscan2
- UGT8 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 65/248 reads (26%) | catalogued as COSV60416822; called by muse, mutect2, varscan2
- UGT8 | c.1328G>C p.R443P | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60416831, COSV60417493; called by muse, mutect2, varscan2
- USH1C | c.1292G>T p.R431L | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV50014636; called by muse, mutect2, varscan2
- USH2A | c.14133G>C p.Q4711H | Missense Mutation (SNP) | VAF 58/620 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56340517; called by muse, mutect2
- USP16 | c.2335G>T p.G779C | Missense Mutation (SNP) | VAF 144/267 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54503279; called by muse, varscan2
- USP28 | c.621A>G p.T207= | Splice Region (SNP) | VAF 77/165 reads (47%) | catalogued as COSV50157017; called by muse, mutect2, varscan2
- VPS50 | c.1921C>G p.Q641E | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as rs1176397204, COSV58508456; called by muse, mutect2
- WDR64 | c.1635G>T p.K545N | Missense Mutation (SNP) | VAF 191/709 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV63793566; called by muse, mutect2, varscan2
- WDR7 | c.3376G>T p.A1126S | Missense Mutation (SNP) | VAF 217/651 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV54349774; called by muse, mutect2, varscan2
- WDR87 | c.1414A>T p.T472S | Missense Mutation (SNP) | VAF 276/686 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58195014; called by muse, mutect2, varscan2
- ZBTB26 | c.479A>T p.K160M | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV65402882; called by muse, mutect2, varscan2
- ZIM3 | c.239C>A p.A80E | Missense Mutation (SNP) | VAF 95/471 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54140789; called by muse, mutect2, varscan2
- ZMAT1 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65657962; called by muse, mutect2, varscan2
- ZNF200 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67723568; called by muse, mutect2
- ZNF267 | c.728A>T p.Q243L | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56251202; called by muse, mutect2, varscan2
- ZNF292 | c.5632G>C p.A1878P | Missense Mutation (SNP) | VAF 117/205 reads (57%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV60536767; called by muse, mutect2, varscan2
- ZNF429 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs1254604049; called by muse, mutect2
- ZNF468 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 63/354 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54693734; called by muse, mutect2, varscan2
- ZNF528 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100846622; called by muse, mutect2
- ZNF606 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58705333; called by muse, mutect2, varscan2
- ZNF711 | c.2146G>T p.A716S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV52152306; called by muse, varscan2
- ZNF724 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 141/432 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as rs1269346441; called by muse, mutect2, varscan2
- ZNF99 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 114/693 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV101233914; called by muse, mutect2, varscan2
- ZNRF4 | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as rs1231308071, COSV55773275; called by muse, mutect2, varscan2
- ZSCAN5C | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 161/386 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs372171239; called by muse, mutect2, varscan2
- AAMP | c.1283G>C p.C428S | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.116); called by muse, mutect2
- ABCA13 | c.9443T>A p.L3148Q | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCB4 | c.2927T>A p.V976E | Missense Mutation (SNP) | VAF 64/971 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ABCG2 | c.653C>A p.S218* | Nonsense Mutation (SNP) | VAF 58/213 reads (27%) | called by muse, mutect2, varscan2
- ACADM | c.386_387insT p.Q130Afs*10 | Frame Shift Ins (INS) | VAF 83/572 reads (15%) | called by mutect2, varscan2
- ACSS2 | c.899G>T p.C300F | Missense Mutation (SNP) | VAF 71/876 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2
- ADAMTS2 | c.2485T>C p.S829P | Missense Mutation (SNP) | VAF 82/1479 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2
- AHI1 | c.3204T>G p.D1068E | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AHI1 | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKAP14 | c.293del p.G98Afs*2 | Frame Shift Del (DEL) | VAF 56/208 reads (27%) | called by mutect2, pindel, varscan2
- AMPD3 | c.320C>T p.S107F (on ENST00000396553 / NM_001025389.2; = p.S116F on NM_000480.3) | Missense Mutation (SNP) | VAF 74/766 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2
- AMY2B | c.1101+2T>A p.X367_splice | Splice Site (SNP) | VAF 74/650 reads (11%) | called by muse, mutect2, varscan2
- ANKRD26 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 112/267 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- ANTXRL | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 137/228 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- APP | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 224/558 reads (40%) | called by muse, mutect2, varscan2
- ASF1A | c.108A>C p.E36D | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, varscan2
- ATP5PB | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 80/365 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- B4GALNT3 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BEND4 | c.1567G>T p.V523F | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- C4B | c.3727C>A p.P1243T | Missense Mutation (SNP) | VAF 66/1496 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); called by muse, mutect2
- C6orf58 | c.355_357del p.H119del | In Frame Del (DEL) | VAF 19/127 reads (15%) | called by mutect2, pindel, varscan2
- CCDC102B | c.119G>T p.C40F | Missense Mutation (SNP) | VAF 170/693 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC59 | c.525G>T p.L175F | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2
- CDC14C | c.1468C>A p.P490T (on ENST00000428251; = p.P383T on NM_152627.3) | Missense Mutation (SNP) | VAF 33/355 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH10 | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 38/1034 reads (4%) | called by muse, mutect2
- CDH7 | c.1557C>A p.F519L | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CEMIP2 | c.4020T>A p.S1340R | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CEP170 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 132/584 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CETP | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 21/607 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2
- CFH | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 29/559 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.043); called by muse, mutect2
- CGB1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 24/824 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTNAP3 | c.3236G>T p.R1079M | Missense Mutation (SNP) | VAF 74/547 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- COPA | c.2278C>T p.L760F | Missense Mutation (SNP) | VAF 24/666 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- DDR1 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- DENND1A | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2
- DENND4B | c.2152C>G p.Q718E | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- DIP2B | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH9 | c.6069C>A p.F2023L | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- DNTTIP1 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 18/670 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- DPP6 | c.327del p.I110Sfs*8 (on ENST00000377770 / NM_001364500.2; = p.I48Sfs*8 on NM_001936.5) | Frame Shift Del (DEL) | VAF 24/166 reads (14%) | called by mutect2, pindel, varscan2
- DPP7 | c.903G>C p.Q301H | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DYNC1H1 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- EFCAB3 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.11); called by muse, mutect2
- EPS15 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- EXOC1 | c.1331-4A>G | Splice Region (SNP) | VAF 28/425 reads (7%) | called by muse, mutect2
- FAM90A1 | c.674T>A p.V225E | Missense Mutation (SNP) | VAF 157/2328 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- FKBP1C | c.121del p.R41Gfs*11 | Frame Shift Del (DEL) | VAF 395/823 reads (48%) | called by mutect2, pindel, varscan2
- FOXA3 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 58/822 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- FSIP2 | c.17992T>C p.C5998R | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GDF10 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 127/411 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GP6 | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 72/980 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- GPAA1 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 41/686 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRM6 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HHATL | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 49/512 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HLA-E | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- HNRNPUL2 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HRH3 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 63/928 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- HTD2 | c.261G>T p.L87F | Missense Mutation (SNP) | VAF 49/485 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HYDIN | c.12049G>A p.E4017K | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- IFI30 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- IGHV1-2 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 99/690 reads (14%) | called by muse, mutect2, varscan2
- IGHV3-49 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 80/624 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- IGKV1-12 | c.325T>A p.Y109N | Missense Mutation (SNP) | VAF 82/1396 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- IGKV5-2 | c.73A>T p.T25S | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- IL21R | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- ING4 | c.71A>G p.N24S | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- INTS4 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.062); called by muse, mutect2
- ITGAV | c.241del p.V81Wfs*48 | Frame Shift Del (DEL) | VAF 55/290 reads (19%) | called by mutect2, pindel, varscan2
- KASH5 | c.1460_1476del p.Q487Rfs*85 | Frame Shift Del (DEL) | VAF 48/323 reads (15%) | called by mutect2, pindel
- KBTBD8 | c.312_320del p.L105_Y107del | In Frame Del (DEL) | VAF 40/492 reads (8%) | called by mutect2, pindel
- KCNH7 | c.1819G>T p.G607* | Nonsense Mutation (SNP) | VAF 27/418 reads (6%) | called by muse, mutect2
- KCTD3 | c.1661A>T p.Y554F | Missense Mutation (SNP) | VAF 53/511 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- KDM5D | c.271A>G p.K91E | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- KIAA1671 | c.2092C>G p.H698D | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.189); called by muse, mutect2
- KIAA2026 | c.2241C>G p.I747M | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2
- KIF3B | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); called by muse, mutect2
- KIF4A | c.2388+1G>A p.X796_splice | Splice Site (SNP) | VAF 64/203 reads (32%) | called by muse, mutect2, varscan2
- KIRREL1 | c.315del p.A106Pfs*25 | Frame Shift Del (DEL) | VAF 129/501 reads (26%) | called by mutect2, pindel, varscan2
- KMT2C | c.2903A>G p.Q968R | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- KRTAP6-3 | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 88/506 reads (17%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP9-9 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 254/1288 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- LAMB1 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2
- LANCL2 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 25/346 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- LRP2 | c.310+1G>T p.X104_splice | Splice Site (SNP) | VAF 72/744 reads (10%) | called by muse, mutect2
- LRRTM1 | c.1292del p.G431Afs*72 | Frame Shift Del (DEL) | VAF 133/345 reads (39%) | called by mutect2, pindel, varscan2
- MAGEH1 | c.419_420del p.F140Cfs*9 | Frame Shift Del (DEL) | VAF 32/325 reads (10%) | called by mutect2, pindel, varscan2
- MAJIN | c.349+2T>A p.X117_splice | Splice Site (SNP) | VAF 95/201 reads (47%) | called by muse, mutect2, varscan2
- MGAM | c.4258-2A>T p.X1420_splice | Splice Site (SNP) | VAF 58/429 reads (14%) | called by muse, mutect2, varscan2
- MGAM2 | c.1936G>T p.A646S | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUC6 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- NAA35 | c.285T>G p.I95M | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.472); called by muse, mutect2
- NCR3LG1 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 47/260 reads (18%) | called by muse, mutect2, varscan2
- NDC80 | c.1583G>A p.C528Y | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NDST3 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, varscan2
- NFYC | c.1304_1313del p.L435Pfs*18 (on ENST00000308733 / NM_001308114.1; = p.L312Pfs*18 on NM_014223.5) | Frame Shift Del (DEL) | VAF 164/616 reads (27%) | called by mutect2, pindel, varscan2
- NLGN2 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 54/617 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPAT | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 107/772 reads (14%) | called by muse, mutect2, varscan2
- NRXN3 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5L2 | c.371del p.V124Gfs*11 | Frame Shift Del (DEL) | VAF 50/210 reads (24%) | called by mutect2, pindel*, varscan2
- OR6J1 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2
- OSBPL3 | c.1780G>T p.A594S | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- PAEP | c.422-5C>A | Splice Region (SNP) | VAF 63/304 reads (21%) | called by muse, mutect2, varscan2
- PAH | c.1356G>T p.K452N | Missense Mutation (SNP) | VAF 35/360 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); called by muse, mutect2
- PCNT | c.2140G>C p.D714H | Missense Mutation (SNP) | VAF 54/557 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- PHGR1 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 78/170 reads (46%) | PolyPhen probably damaging (0.973); called by muse, varscan2
- PLCB1 | c.2931-1G>T p.X977_splice | Splice Site (SNP) | VAF 67/144 reads (47%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.87-2A>T p.X29_splice | Splice Site (SNP) | VAF 77/156 reads (49%) | called by muse, mutect2, varscan2
- PODXL2 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 30/443 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- POLN | c.2065+1G>T p.X689_splice | Splice Site (SNP) | VAF 191/533 reads (36%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 134/2776 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2
- PRAMEF19 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 140/748 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, varscan2
- PRKG2 | c.2046G>C p.L682F | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2
- PSMB2 | c.285+1G>T p.X95_splice | Splice Site (SNP) | VAF 82/227 reads (36%) | called by muse, mutect2, varscan2
- RAB3IL1 | c.600C>A p.C200* | Nonsense Mutation (SNP) | VAF 81/181 reads (45%) | called by muse, mutect2, varscan2
- RBL2 | c.992+1_992+34del p.X331_splice | Splice Site (DEL) | VAF 29/157 reads (18%) | called by mutect2, pindel
- RBM6 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 15/285 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- RFX4 | c.2120C>A p.T707K (on ENST00000392842 / NM_213594.3; = p.T613K on NM_032491.6) | Missense Mutation (SNP) | VAF 216/468 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.1); called by mutect2, varscan2
- RGPD3 | c.2321C>A p.S774* | Nonsense Mutation (SNP) | VAF 357/1450 reads (25%) | called by muse, mutect2, varscan2
- ROCK1 | c.3872C>G p.S1291* | Nonsense Mutation (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- RYR1 | c.6127+2T>C p.X2043_splice | Splice Site (SNP) | VAF 159/773 reads (21%) | called by muse, mutect2, varscan2
- SARS2 | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2
- SCAF1 | c.2779G>T p.V927F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2
- SCG2 | c.605del p.F202Sfs*7 | Frame Shift Del (DEL) | VAF 59/544 reads (11%) | called by mutect2, pindel, varscan2
- SH3RF3 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2
- SHANK1 | c.3235G>T p.G1079C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SI | c.4287T>A p.D1429E | Missense Mutation (SNP) | VAF 93/533 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- SIX4 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLC10A4 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A1 | c.1147A>G p.I383V | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.009); called by muse, mutect2
- SLC7A5 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 42/666 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2
- SLITRK1 | c.718del p.V240Sfs*24 | Frame Shift Del (DEL) | VAF 148/483 reads (31%) | called by mutect2, pindel, varscan2
- STAC2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SVEP1 | c.2366-1G>C p.X789_splice | Splice Site (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- SYBU | c.1761G>C p.L587F (on ENST00000276646 / NM_001099754.2; = p.L586F on NM_017786.6) | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2
- SYNCRIP | c.71C>G p.S24* | Nonsense Mutation (SNP) | VAF 16/363 reads (4%) | called by muse, mutect2
- TBX18 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TCF12 | c.106A>C p.T36P | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TCP11X2 | c.1323G>T p.M441I | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.049); called by mutect2, varscan2
- TDRD12 | c.2921C>A p.T974K (on ENST00000444215; = p.T979K on NM_001366102.1) | Missense Mutation (SNP) | VAF 155/827 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TDRD15 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.471); called by muse, mutect2
- TEAD3 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2
- TEAD4 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2
- TGM2 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 44/891 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.659); called by muse, mutect2
- TLE2 | c.1489C>G p.L497V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- TLR6 | c.1548G>T p.Q516H | Missense Mutation (SNP) | VAF 120/636 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TNFAIP2 | c.1205A>C p.Q402P | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TNNI3K | c.2494G>C p.E832Q | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- TRA2B | c.481T>A p.F161I | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRAPPC9 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 95/1116 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); called by muse, mutect2
- TRIP11 | c.4115G>A p.R1372K | Missense Mutation (SNP) | VAF 74/982 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- UBR2 | c.3292C>G p.Q1098E | Missense Mutation (SNP) | VAF 52/822 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- UGT2A1 | c.1420C>A p.L474I | Missense Mutation (SNP) | VAF 130/561 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- UNC13A | c.2753C>G p.S918C | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- USH2A | c.3236C>T p.S1079F | Missense Mutation (SNP) | VAF 79/922 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- USP35 | c.1691C>A p.T564N | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VGLL4 | c.580A>T p.S194C | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- VIL1 | c.1813del p.A605Pfs*48 | Frame Shift Del (DEL) | VAF 40/167 reads (24%) | called by mutect2, pindel, varscan2
- VPS4B | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 22/257 reads (9%) | called by muse, mutect2
- ZNF148 | c.384G>C p.M128I | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- ZNF629 | c.933C>G p.I311M | Missense Mutation (SNP) | VAF 42/522 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF695 | c.464del p.N155Tfs*8 | Frame Shift Del (DEL) | VAF 39/163 reads (24%) | called by mutect2, pindel, varscan2
- ZNF729 | c.3623C>G p.T1208R | Missense Mutation (SNP) | VAF 143/745 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZSCAN5C | c.26G>A p.W9* | Nonsense Mutation (SNP) | VAF 63/145 reads (43%) | called by muse, mutect2, varscan2
- ABHD8 | c.135G>T p.R45= | Silent (SNP) | VAF 108/229 reads (47%) | catalogued as COSV53112662; called by muse, mutect2, varscan2
- ACP4 | c.63G>T p.V21= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV54516424; called by muse, mutect2, varscan2
- ACP6 | c.417G>C p.L139= | Silent (SNP) | VAF 18/660 reads (3%) | called by muse, mutect2
- AHCTF1 | c.6387C>T p.S2129= (on ENST00000366508; = p.S2103= on NM_015446.5) | Silent (SNP) | VAF 342/869 reads (39%) | catalogued as COSV100403941; called by muse, mutect2, varscan2
- ALK | c.1755C>A p.A585= | Silent (SNP) | VAF 86/415 reads (21%) | catalogued as COSV66556938; called by muse, varscan2
- AMER3 | c.744G>T p.T248= | Silent (SNP) | VAF 75/247 reads (30%) | catalogued as COSV58465643; called by muse, mutect2, varscan2
- AMY2A | c.585C>A p.A195= | Silent (SNP) | VAF 98/2004 reads (5%) | catalogued as COSV70214322; called by muse, mutect2
- ANKRD26 | c.81G>T p.G27= | Silent (SNP) | VAF 118/274 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.141C>A p.T47= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV54484117; called by muse, mutect2, varscan2
- ASZ1 | c.39C>G p.G13= | Silent (SNP) | VAF 89/349 reads (26%) | catalogued as rs750013955, COSV52911757; called by muse, mutect2, varscan2
- ATRNL1 | c.1572T>C p.H524= | Silent (SNP) | VAF 12/222 reads (5%) | catalogued as COSV61796788; called by muse, mutect2
- C1orf167 | c.2455C>T p.L819= | Silent (SNP) | VAF 48/153 reads (31%) | called by muse, mutect2, varscan2
- C4orf54 | c.3751C>A p.R1251= | Silent (SNP) | VAF 141/524 reads (27%) | called by muse, mutect2, varscan2
- CACNA1B | c.3648G>T p.R1216= | Silent (SNP) | VAF 214/854 reads (25%) | catalogued as COSV53117891; called by muse, mutect2, varscan2
- CACNA2D1 | c.420A>T p.P140= | Silent (SNP) | VAF 117/336 reads (35%) | catalogued as COSV62375158; called by muse, mutect2, varscan2
- CACNA2D4 | c.1584G>A p.L528= | Silent (SNP) | VAF 13/243 reads (5%) | called by muse, mutect2
- CALN1 | c.276G>T p.V92= (on ENST00000329008 / NM_001017440.3; = p.V134= on NM_031468.4) | Silent (SNP) | VAF 81/199 reads (41%) | catalogued as rs754103325, COSV61123639; called by muse, mutect2, varscan2
- CCDC102B | c.1134A>G p.R378= | Silent (SNP) | VAF 53/274 reads (19%) | called by muse, mutect2, varscan2
- CCNL2 | c.462G>C p.L154= | Silent (SNP) | VAF 20/232 reads (9%) | catalogued as COSV61224421; called by muse, mutect2
- CFAP74 | c.3315G>T p.R1105= | Silent (SNP) | VAF 60/221 reads (27%) | called by muse, mutect2, varscan2
- CGN | c.2169G>T p.T723= | Silent (SNP) | VAF 65/578 reads (11%) | called by muse, mutect2, varscan2
- CHL1 | c.1380G>T p.V460= (on ENST00000397491 / NM_001253387.1; = p.V476= on NM_006614.4) | Silent (SNP) | VAF 84/150 reads (56%) | catalogued as COSV56585627; called by muse, varscan2
- CPN2 | c.600G>T p.L200= | Silent (SNP) | VAF 329/745 reads (44%) | catalogued as COSV60469814; called by muse, mutect2, varscan2
- CSMD2 | c.6486G>T p.T2162= | Silent (SNP) | VAF 44/360 reads (12%) | catalogued as COSV53889587, COSV53944433; called by muse, mutect2, varscan2
- CSNK1G2 | c.531G>A p.G177= | Silent (SNP) | VAF 40/299 reads (13%) | catalogued as rs753651278, COSV55337942; called by muse, mutect2, varscan2
- CUBN | c.8994G>T p.V2998= | Silent (SNP) | VAF 305/947 reads (32%) | catalogued as COSV64710235; called by muse, mutect2, varscan2
- CUX2 | c.1116G>A p.L372= | Silent (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- CYP3A5 | c.1508G>A p.*503= | Silent (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- DACT2 | c.1369C>A p.R457= | Silent (SNP) | VAF 32/374 reads (9%) | catalogued as COSV64695064; called by muse, mutect2
- DHRS4L2 | c.318T>C p.L106= | Silent (SNP) | VAF 106/404 reads (26%) | catalogued as COSV58728904; called by muse, mutect2, varscan2
- DTYMK | c.201G>C p.S67= | Silent (SNP) | VAF 31/444 reads (7%) | catalogued as rs574574617; called by muse, mutect2
- EMILIN2 | c.2556G>C p.G852= | Silent (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- ESPNL | c.2601G>A p.E867= | Silent (SNP) | VAF 33/389 reads (8%) | called by muse, mutect2
- FAM124B | c.1140C>T p.G380= | Silent (SNP) | VAF 66/768 reads (9%) | catalogued as rs375635395; called by muse, mutect2
- FAM135B | c.3045T>A p.T1015= | Silent (SNP) | VAF 44/258 reads (17%) | catalogued as COSV52712182; called by muse, mutect2, varscan2
- FAP | c.1086T>A p.I362= | Silent (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- FCRL5 | c.1818C>A p.T606= | Silent (SNP) | VAF 101/441 reads (23%) | catalogued as COSV62512706; called by muse, mutect2, varscan2
- FN3K | c.777C>T p.F259= | Silent (SNP) | VAF 72/962 reads (7%) | called by muse, mutect2
- GMPPA | c.513C>G p.P171= | Silent (SNP) | VAF 69/336 reads (21%) | catalogued as COSV58006299; called by muse, mutect2, varscan2
- GNAS | c.336C>T p.N112= | Silent (SNP) | VAF 296/2030 reads (15%) | catalogued as COSV55672759; called by muse, mutect2, varscan2
- GOLGA8F | c.702A>C p.A234= (on ENST00000526619; = p.A440= on NM_001350920.2) | Silent (SNP) | VAF 53/590 reads (9%) | catalogued as rs1305494037; called by muse, mutect2
- GOLGA8S | c.1296A>C p.A432= | Silent (SNP) | VAF 48/409 reads (12%) | called by muse, varscan2
- GPR26 | c.546G>T p.L182= | Silent (SNP) | VAF 96/237 reads (41%) | catalogued as COSV52933126; called by muse, mutect2, varscan2
- GRIN2C | c.1128G>A p.E376= | Silent (SNP) | VAF 31/481 reads (6%) | catalogued as rs774554426; called by muse, mutect2
- GSX1 | c.651G>T p.G217= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV57232558; called by muse, mutect2, varscan2
- GYPC | c.33G>A p.A11= | Silent (SNP) | VAF 64/369 reads (17%) | catalogued as rs750504297, COSV99391611; called by muse, mutect2, varscan2
- INTS1 | c.3534G>T p.P1178= | Silent (SNP) | VAF 50/334 reads (15%) | catalogued as rs575924379, COSV67176701; called by muse, mutect2, varscan2
- ISLR | c.771T>C p.C257= | Silent (SNP) | VAF 96/199 reads (48%) | catalogued as COSV51433243; called by muse, mutect2, varscan2
- JAG2 | c.255G>T p.T85= | Silent (SNP) | VAF 95/310 reads (31%) | catalogued as COSV59307429; called by muse, mutect2, varscan2
- JPH3 | c.312G>A p.G104= | Silent (SNP) | VAF 63/355 reads (18%) | called by muse, mutect2, varscan2
- KAT2B | c.2439C>T p.A813= | Silent (SNP) | VAF 15/448 reads (3%) | called by muse, mutect2
- KAT6B | c.6147G>T p.T2049= | Silent (SNP) | VAF 497/827 reads (60%) | catalogued as COSV54743882; called by muse, mutect2, varscan2
- KCNH1 | c.1641C>A p.S547= (on ENST00000271751 / NM_172362.3; = p.S520= on NM_002238.4) | Silent (SNP) | VAF 60/632 reads (9%) | catalogued as COSV99659231; called by muse, mutect2
- KCNU1 | c.2730G>T p.L910= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV67754024; called by muse, mutect2, varscan2
- KIRREL2 | c.1314C>T p.F438= | Silent (SNP) | VAF 26/278 reads (9%) | called by muse, mutect2
- KLK3 | c.639T>A p.S213= | Silent (SNP) | VAF 64/138 reads (46%) | catalogued as COSV58099431; called by muse, mutect2, varscan2
- LAMA5 | c.2904C>T p.A968= | Silent (SNP) | VAF 163/236 reads (69%) | catalogued as COSV53355099; called by muse, mutect2, varscan2
- LGR6 | c.2211G>A p.V737= (on ENST00000367278 / NM_001017403.1; = p.V685= on NM_021636.3) | Silent (SNP) | VAF 38/786 reads (5%) | called by muse, mutect2
- LRP12 | c.1719T>G p.S573= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as COSV52626951; called by muse, mutect2, varscan2
- LY9 | c.948C>A p.S316= | Silent (SNP) | VAF 259/750 reads (35%) | catalogued as COSV54432284; called by muse, mutect2, varscan2
- MAP4 | c.1416G>T p.V472= | Silent (SNP) | VAF 61/588 reads (10%) | catalogued as COSV64237183; called by muse, mutect2, varscan2
- MAP4K1 | c.603G>T p.L201= | Silent (SNP) | VAF 68/398 reads (17%) | called by muse, mutect2, varscan2
- MOB2 | c.675G>A p.P225= | Silent (SNP) | VAF 170/379 reads (45%) | catalogued as rs758260810, COSV57318068, COSV57319129; called by muse, mutect2, varscan2
- MPDZ | c.3831C>T p.N1277= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as rs1347939031; called by muse, mutect2, varscan2
- MS4A4A | c.441G>T p.G147= | Silent (SNP) | VAF 58/329 reads (18%) | catalogued as COSV59700089, COSV59702065; called by muse, mutect2, varscan2
- MSR1 | c.922C>A p.R308= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV50508193, COSV50540950; called by muse, mutect2, varscan2
- NIFK | c.684G>T p.V228= | Silent (SNP) | VAF 80/197 reads (41%) | catalogued as COSV53534425; called by muse, mutect2, varscan2
- NLRP11 | c.2139G>T p.L713= | Silent (SNP) | VAF 48/272 reads (18%) | called by muse, mutect2, varscan2
- OAF | c.561T>A p.S187= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as COSV61108928; called by muse, mutect2
- OR10R2 | c.642T>A p.V214= | Silent (SNP) | VAF 154/358 reads (43%) | catalogued as COSV63768589; called by muse, mutect2, varscan2
- OR14A2 | c.360C>A p.R120= | Silent (SNP) | VAF 93/363 reads (26%) | called by muse, mutect2, varscan2
- OR1N2 | c.96C>A p.G32= | Silent (SNP) | VAF 33/287 reads (11%) | catalogued as COSV65460341; called by muse, mutect2, varscan2
- OR2A7 | c.327A>C p.T109= | Silent (SNP) | VAF 121/830 reads (15%) | called by muse, mutect2, varscan2
- OR2G2 | c.936G>T p.L312= | Silent (SNP) | VAF 50/314 reads (16%) | catalogued as rs267598474, COSV60739768; called by muse, varscan2
- OR2T27 | c.216G>T p.L72= | Silent (SNP) | VAF 59/518 reads (11%) | catalogued as COSV61281175; called by muse, mutect2, varscan2
- OR4K14 | c.813G>C p.L271= | Silent (SNP) | VAF 142/458 reads (31%) | catalogued as COSV59292258, COSV59292392; called by muse, mutect2, varscan2
- OR4Q3 | c.441C>A p.P147= | Silent (SNP) | VAF 25/273 reads (9%) | catalogued as COSV59177689; called by muse, mutect2
- OR8B2 | c.816T>A p.V272= | Silent (SNP) | VAF 45/182 reads (25%) | called by muse, mutect2
- OR8B8 | c.612C>A p.G204= | Silent (SNP) | VAF 280/660 reads (42%) | catalogued as COSV60144095; called by muse, mutect2, varscan2
- OTOF | c.300G>T p.L100= | Silent (SNP) | VAF 152/629 reads (24%) | catalogued as COSV55498402; called by muse, mutect2, varscan2
- OTOP3 | c.1164G>T p.T388= | Silent (SNP) | VAF 250/724 reads (35%) | catalogued as rs764918488, COSV60912595; called by muse, mutect2, varscan2
- P2RX5 | c.300C>T p.V100= | Silent (SNP) | VAF 80/323 reads (25%) | catalogued as COSV56591111; called by muse, mutect2, varscan2
- P3H2 | c.1143G>T p.L381= | Silent (SNP) | VAF 209/619 reads (34%) | catalogued as COSV60019382; called by muse, mutect2, varscan2
- PADI2 | c.1377C>A p.P459= | Silent (SNP) | VAF 98/308 reads (32%) | catalogued as COSV64945440; called by muse, mutect2
- PCDHB3 | c.522G>A p.P174= | Silent (SNP) | VAF 82/324 reads (25%) | catalogued as COSV50565788; called by muse, mutect2, varscan2
- PCSK5 | c.1839A>G p.E613= | Silent (SNP) | VAF 21/236 reads (9%) | called by muse, mutect2
- PDGFRA | c.2496G>T p.V832= | Silent (SNP) | VAF 38/839 reads (5%) | called by muse, mutect2
- PLCL1 | c.3186T>C p.C1062= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- PLEC | c.948A>T p.R316= (on ENST00000322810 / NM_201380.4; = p.R206= on NM_000445.5) | Silent (SNP) | VAF 72/882 reads (8%) | catalogued as COSV59611738, COSV59613189; called by muse, mutect2
- PLPPR5 | c.210G>T p.S70= | Silent (SNP) | VAF 43/205 reads (21%) | called by muse, mutect2, varscan2
- PLXDC1 | c.1332A>C p.G444= | Silent (SNP) | VAF 69/306 reads (23%) | catalogued as COSV59550052; called by muse, mutect2, varscan2
- PLXNB1 | c.3711G>T p.T1237= | Silent (SNP) | VAF 42/180 reads (23%) | catalogued as COSV56487712; called by muse, mutect2, varscan2
- PLXNC1 | c.2511C>T p.T837= | Silent (SNP) | VAF 308/683 reads (45%) | catalogued as COSV51571267; called by muse, mutect2, varscan2
- PNLIPRP2 | c.1380C>T p.N460= (on ENST00000611850; = p.N461= on NM_005396.5) | Silent (SNP) | VAF 18/360 reads (5%) | catalogued as rs782387882, COSV53943659; called by muse, mutect2
- PRG4 | c.21C>A p.P7= | Silent (SNP) | VAF 70/1222 reads (6%) | catalogued as rs756483451, COSV100825734, COSV66624048; called by muse, mutect2
- PRSS16 | c.702C>T p.I234= | Silent (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- PTPRC | c.1464C>G p.V488= | Silent (SNP) | VAF 365/960 reads (38%) | catalogued as COSV61408160; called by muse, mutect2, varscan2
- PTX4 | c.453G>A p.Q151= (on ENST00000447419 / NM_001328608.2; = p.Q146= on NM_001013658.1) | Silent (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- QARS1 | c.435C>T p.N145= | Silent (SNP) | VAF 22/171 reads (13%) | called by muse, mutect2, varscan2
- RELN | c.6160C>T p.L2054= | Silent (SNP) | VAF 89/1819 reads (5%) | catalogued as rs1301196919; called by muse, mutect2
- RFX6 | c.1080C>T p.S360= | Silent (SNP) | VAF 224/417 reads (54%) | catalogued as rs1162676232; called by muse, mutect2, varscan2
- RNF130 | c.186G>A p.G62= | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as rs755550389, COSV56149024; called by muse, varscan2
- RSF1 | c.24G>A p.A8= | Silent (SNP) | VAF 63/235 reads (27%) | catalogued as rs1386128396; called by muse, mutect2, varscan2
- RUNX3 | c.579G>T p.P193= | Silent (SNP) | VAF 86/301 reads (29%) | catalogued as COSV100137021; called by muse, mutect2, varscan2
- RYR2 | c.10812G>T p.R3604= | Silent (SNP) | VAF 47/245 reads (19%) | catalogued as COSV63670860; called by muse, mutect2
- SCN4A | c.690C>A p.I230= | Silent (SNP) | VAF 134/377 reads (36%) | catalogued as COSV71125987; called by muse, mutect2, varscan2
- SCN5A | c.2982C>A p.A994= | Silent (SNP) | VAF 16/191 reads (8%) | catalogued as COSV61114875, COSV61118918; called by muse, mutect2
- SENP5 | c.1500A>T p.S500= | Silent (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2
- SEPTIN4 | c.919C>A p.R307= | Silent (SNP) | VAF 121/386 reads (31%) | catalogued as COSV57894954; called by muse, mutect2, varscan2
- SETBP1 | c.2766C>T p.L922= | Silent (SNP) | VAF 42/612 reads (7%) | called by muse, mutect2
- SF3B2 | c.2256A>T p.S752= | Silent (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- SLC10A1 | c.804C>G p.T268= | Silent (SNP) | VAF 30/185 reads (16%) | called by muse, mutect2, varscan2
- SLC13A4 | c.93C>A p.P31= | Silent (SNP) | VAF 30/227 reads (13%) | called by muse, mutect2, varscan2
- SLC22A6 | c.1242G>A p.V414= | Silent (SNP) | VAF 30/330 reads (9%) | catalogued as rs748076996, COSV64559696; called by muse, mutect2
- SLC4A11 | c.1866C>G p.L622= | Silent (SNP) | VAF 58/875 reads (7%) | called by muse, mutect2
- SLC9A9 | c.927G>A p.P309= | Silent (SNP) | VAF 143/655 reads (22%) | catalogued as rs144088456; called by muse, mutect2, varscan2
- SLIT3 | c.4056G>T p.V1352= | Silent (SNP) | VAF 105/558 reads (19%) | catalogued as COSV100266010; called by muse, mutect2, varscan2
- SPTBN5 | c.2751G>T p.V917= | Silent (SNP) | VAF 85/190 reads (45%) | catalogued as COSV58017898; called by muse, mutect2, varscan2
- STAB1 | c.5007G>T p.G1669= | Silent (SNP) | VAF 85/138 reads (62%) | catalogued as rs1205860894, COSV58733412; called by muse, mutect2, varscan2
- STARD8 | c.168G>T p.P56= | Silent (SNP) | VAF 69/200 reads (35%) | catalogued as COSV52923045; called by muse, mutect2, varscan2
- SYNE4 | c.105C>G p.P35= | Silent (SNP) | VAF 36/546 reads (7%) | called by muse, mutect2
- SYNGR1 | c.144C>T p.Y48= | Silent (SNP) | VAF 198/504 reads (39%) | catalogued as COSV53367840; called by muse, mutect2, varscan2
- TAAR2 | c.804A>T p.I268= (on ENST00000367931 / NM_001033080.1; = p.I223= on NM_014626.3) | Silent (SNP) | VAF 68/234 reads (29%) | catalogued as COSV51578649; called by muse, mutect2, varscan2
- TAF1L | c.3078A>T p.L1026= | Silent (SNP) | VAF 46/736 reads (6%) | catalogued as COSV54259433; called by muse, mutect2
- TFCP2 | c.1344C>T p.F448= | Silent (SNP) | VAF 36/400 reads (9%) | called by muse, mutect2
- TMEM132D | c.2346G>T p.R782= | Silent (SNP) | VAF 136/461 reads (30%) | catalogued as COSV67159334; called by muse, mutect2, varscan2
- TMEM178B | c.795G>T p.S265= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as rs990597433, COSV73803190; called by muse, mutect2, varscan2
- TMEM259 | c.363C>A p.R121= | Silent (SNP) | VAF 168/389 reads (43%) | catalogued as COSV52259027, COSV99312265; called by muse, mutect2, varscan2
- TOGARAM1 | c.4290G>T p.G1430= | Silent (SNP) | VAF 42/158 reads (27%) | called by muse, mutect2, varscan2
- TRBV20-1 | c.288C>T p.T96= | Silent (SNP) | VAF 43/330 reads (13%) | catalogued as rs945306694; called by muse, mutect2, varscan2
- TTBK2 | c.504A>G p.R168= | Silent (SNP) | VAF 223/450 reads (50%) | called by muse, mutect2, varscan2
- TYK2 | c.729G>T p.R243= | Silent (SNP) | VAF 54/341 reads (16%) | catalogued as rs900351715, COSV53385567; called by muse, mutect2, varscan2
- UGT2B7 | c.1431G>C p.R477= | Silent (SNP) | VAF 107/463 reads (23%) | called by muse, mutect2, varscan2
- USH2A | c.8373C>T p.V2791= | Silent (SNP) | VAF 119/826 reads (14%) | catalogued as COSV56340528; called by muse, mutect2, varscan2
- VIPR2 | c.510C>A p.I170= | Silent (SNP) | VAF 57/234 reads (24%) | catalogued as COSV51104141; called by muse, mutect2, varscan2
- VPS41 | c.639T>A p.L213= | Silent (SNP) | VAF 82/231 reads (35%) | called by muse, mutect2, varscan2
- VWC2 | c.339C>A p.P113= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV61483207; called by muse, mutect2, varscan2
- WDR37 | c.966C>T p.H322= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as rs201819074; called by muse, mutect2
- WWC2 | c.3534C>T p.T1178= | Silent (SNP) | VAF 28/353 reads (8%) | called by muse, mutect2
- WWOX | c.954G>T p.S318= | Silent (SNP) | VAF 446/747 reads (60%) | catalogued as COSV68347197, COSV68349202; called by muse, mutect2, varscan2
- XDH | c.3114G>A p.E1038= | Silent (SNP) | VAF 93/915 reads (10%) | called by muse, mutect2, varscan2
- XPO5 | c.57C>T p.V19= | Silent (SNP) | VAF 61/300 reads (20%) | catalogued as rs1401957263; called by muse, mutect2, varscan2
- ZAN | c.5076G>T p.L1692= | Silent (SNP) | VAF 90/285 reads (32%) | called by muse, mutect2
- ZAR1 | c.666C>T p.G222= | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- ZNF10 | c.414G>A p.K138= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV50211727; called by muse, mutect2, varscan2
- ZNF607 | c.1755T>A p.G585= | Silent (SNP) | VAF 129/294 reads (44%) | catalogued as COSV67696437; called by muse, mutect2, varscan2
- ZNF879 | c.126G>A p.V42= | Silent (SNP) | VAF 243/732 reads (33%) | catalogued as COSV71423830; called by muse, mutect2, varscan2
- AAK1 | c.*14233G>T | 3'UTR (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- AC006305.1 | n.1164A>G | RNA (SNP) | VAF 32/139 reads (23%) | called by muse, mutect2, varscan2
- AC090155.1 | n.362A>G | RNA (SNP) | VAF 32/240 reads (13%) | called by muse, varscan2
- AC107023.1 | n.26-11346C>A | Intron (SNP) | VAF 33/341 reads (10%) | called by muse, mutect2
- ACVR2A | c.-7C>T | 5'UTR (SNP) | VAF 28/308 reads (9%) | catalogued as rs746867155; called by muse, mutect2
- ADAM20P1 | n.733G>T | RNA (SNP) | VAF 30/104 reads (29%) | catalogued as rs1448753070; called by muse, varscan2
- AGAP7P | n.1062C>A | RNA (SNP) | VAF 161/1762 reads (9%) | called by muse, mutect2
- AGPAT4 | c.348+543C>T | Intron (SNP) | VAF 127/255 reads (50%) | called by muse, mutect2, varscan2
- AKT2 | c.-84-9902G>A | Intron (SNP) | VAF 252/572 reads (44%) | called by muse, mutect2, varscan2
- AL441992.2 | c.*1022C>G | 3'UTR (SNP) | VAF 36/211 reads (17%) | catalogued as rs772582400; called by muse, mutect2, varscan2
- ALKBH6 | c.-101+73G>C | Intron (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- AMPH | c.1182+393T>C | Intron (SNP) | VAF 92/428 reads (21%) | catalogued as rs1216375332; called by muse, mutect2
- BRSK2 | c.91+21222G>T | Intron (SNP) | VAF 19/106 reads (18%) | catalogued as rs1438953297; called by muse, mutect2, varscan2
- C6orf201 | c.285-6361T>A | Intron (SNP) | VAF 187/359 reads (52%) | called by muse, mutect2, varscan2
- C8orf87 | n.297C>A | RNA (SNP) | VAF 95/465 reads (20%) | called by muse, mutect2, varscan2
- CCDC144CP | n.2978A>T | RNA (SNP) | VAF 116/557 reads (21%) | called by muse, mutect2, varscan2
- CCM2 | chr7:44999657 C>A | 5'Flank (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- CDCA7 | c.147+633G>C | Intron (SNP) | VAF 29/302 reads (10%) | catalogued as rs1431789324, COSV60720270; called by muse, mutect2
- DCHS2 | n.5154A>G | RNA (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2
- DEAF1 | c.1503+19G>T | Intron (SNP) | VAF 254/616 reads (41%) | called by muse, mutect2
- DEFB121 | n.204A>T | RNA (SNP) | VAF 190/282 reads (67%) | called by muse, mutect2, varscan2
- DPH6 | c.-13C>T | 5'UTR (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- DUXA | c.*4C>G | 3'UTR (SNP) | VAF 113/263 reads (43%) | catalogued as rs1416760664; called by muse, mutect2, varscan2
- EIF2B4 | c.76-49C>T | Intron (SNP) | VAF 38/579 reads (7%) | catalogued as rs1179568309; called by muse, mutect2
- EMBP1 | n.1000A>T | RNA (SNP) | VAF 13/252 reads (5%) | called by muse, mutect2
- EML3 | c.*149C>T | 3'UTR (SNP) | VAF 73/352 reads (21%) | catalogued as rs937465357; called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009885 C>G | 5'Flank (SNP) | VAF 79/453 reads (17%) | called by muse, mutect2, varscan2
- ESPNP | n.139G>T | RNA (SNP) | VAF 28/348 reads (8%) | catalogued as rs771647755; called by muse, mutect2
- ETNK1 | c.-252C>A | 5'UTR (SNP) | VAF 9/69 reads (13%) | catalogued as COSV56884212; called by muse, mutect2, varscan2
- ETNK1 | c.-251C>A | 5'UTR (SNP) | VAF 9/70 reads (13%) | catalogued as COSV56884232; called by muse, mutect2, varscan2
- FCGRT | c.871+57G>C | Intron (SNP) | VAF 151/706 reads (21%) | called by muse, varscan2
- FCRL2 | c.884-66G>T | Intron (SNP) | VAF 112/587 reads (19%) | called by muse, mutect2, varscan2
- FER1L4 | n.4209G>A | RNA (SNP) | VAF 93/786 reads (12%) | catalogued as rs971587993; called by muse, mutect2, varscan2
- FGF6 | c.*19G>T | 3'UTR (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- FGF6 | c.*18G>T | 3'UTR (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- FMO6P | n.1720-122G>T | Intron (SNP) | VAF 73/171 reads (43%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.225A>T | RNA (SNP) | VAF 290/557 reads (52%) | called by muse, mutect2, varscan2
- GALNT13 | c.1396-1061G>T | Intron (SNP) | VAF 31/184 reads (17%) | called by muse, mutect2, varscan2
- GFRA2 | c.41-185C>A | Intron (SNP) | VAF 35/192 reads (18%) | called by muse, mutect2, varscan2
- GVINP1 | n.7070G>T | RNA (SNP) | VAF 110/320 reads (34%) | catalogued as rs1422365261; called by muse, mutect2, varscan2
- HEPACAM | c.-22G>C | 5'UTR (SNP) | VAF 209/520 reads (40%) | catalogued as rs749591373; called by muse, mutect2, varscan2
- HSP90AB3P | n.1588G>T | RNA (SNP) | VAF 160/637 reads (25%) | called by muse, mutect2, varscan2
- IDO1 | c.537+11C>A | Intron (SNP) | VAF 87/303 reads (29%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3033G>T | Intron (SNP) | VAF 40/152 reads (26%) | catalogued as COSV55168194; called by muse, mutect2, varscan2
- IGFN1 | c.1242-1007G>T | Intron (SNP) | VAF 179/599 reads (30%) | catalogued as COSV55168202; called by muse, mutect2, varscan2
- IGKV1D-16 | c.-4C>A | 5'UTR (SNP) | VAF 38/443 reads (9%) | catalogued as rs747504769; called by muse, mutect2
- IL4R | c.70+812C>T | Intron (SNP) | VAF 15/142 reads (11%) | catalogued as rs910286128; called by muse, mutect2
- KCNH5 | c.1369+50del | Intron (DEL) | VAF 26/117 reads (22%) | catalogued as COSV100526125, COSV100526345; called by mutect2, pindel, varscan2
- KIR3DX1 | n.560G>T | RNA (SNP) | VAF 225/604 reads (37%) | catalogued as COSV99682913; called by muse, mutect2, varscan2
- LINC00305 | n.1015A>T | RNA (SNP) | VAF 51/179 reads (28%) | called by muse, mutect2, varscan2
- LINC02876 | n.487G>T | RNA (SNP) | VAF 68/321 reads (21%) | called by muse, mutect2, varscan2
- LRRC37A6P | n.1391C>A | RNA (SNP) | VAF 93/221 reads (42%) | called by muse, mutect2, varscan2
- LRRK2 | c.3496+1625C>T | Intron (SNP) | VAF 76/305 reads (25%) | called by muse, mutect2, varscan2
- MACROH2A1 | c.953+49G>A | Intron (SNP) | VAF 28/316 reads (9%) | catalogued as rs374734622; called by muse, mutect2
- MAGEC3 | c.910-469G>T | Intron (SNP) | VAF 40/118 reads (34%) | catalogued as COSV100025293; called by muse, varscan2
- MIRLET7A2 | n.6G>C | RNA (SNP) | VAF 12/228 reads (5%) | called by muse, mutect2
- MUTYH | c.567+20G>C | Intron (SNP) | VAF 282/1337 reads (21%) | called by muse, mutect2, varscan2
- MYL12A | c.-15-924T>A | Intron (SNP) | VAF 51/223 reads (23%) | called by muse, mutect2, varscan2
- NAGK | chr2:71068530 G>T | 5'Flank (SNP) | VAF 29/65 reads (45%) | catalogued as rs550904969; called by muse, varscan2
- NCAM1 | c.-65C>A | 5'UTR (SNP) | VAF 120/490 reads (24%) | called by muse, mutect2, varscan2
- NPIPB14P | chr16:69976721 C>G | 3'Flank (SNP) | VAF 123/977 reads (13%) | called by muse, mutect2, varscan2
- NPIPB1P | n.730G>C | RNA (SNP) | VAF 87/475 reads (18%) | called by muse, mutect2, varscan2
- NRG3 | c.824-191941T>A | Intron (SNP) | VAF 115/226 reads (51%) | catalogued as COSV64550077; called by muse, mutect2, varscan2
- NSL1 | c.*11240G>T | 3'UTR (SNP) | VAF 104/261 reads (40%) | called by muse, mutect2, varscan2
- NUFIP2 | c.*8G>T | 3'UTR (SNP) | VAF 28/452 reads (6%) | called by muse, mutect2
- PCDHB13 | c.*135G>T | 3'UTR (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- PCYT1A | c.708+67C>T | Intron (SNP) | VAF 26/600 reads (4%) | called by muse, mutect2
- PXN | c.*408C>T | 3'UTR (SNP) | VAF 138/332 reads (42%) | called by muse, mutect2, varscan2
- RAPGEF5 | chr7:22193918 C>A | 5'Flank (SNP) | VAF 98/204 reads (48%) | catalogued as COSV59780184, COSV59787602; called by muse, varscan2
- SEC14L1 | c.2042+119G>A | Intron (SNP) | VAF 98/290 reads (34%) | called by muse, mutect2, varscan2
- SERPINA9 | chr14:94476178 G>T | 5'Flank (SNP) | VAF 58/454 reads (13%) | called by muse, mutect2
- SERPINA9 | chr14:94476180 G>T | 5'Flank (SNP) | VAF 58/460 reads (13%) | called by muse, mutect2
- SLC10A2 | c.*28C>A | 3'UTR (SNP) | VAF 68/264 reads (26%) | catalogued as COSV99808205; called by muse, mutect2, varscan2
- SLC2A14 | c.88-7077G>T | Intron (SNP) | VAF 19/161 reads (12%) | called by muse, varscan2
- SLIT2 | c.1463-639C>G | Intron (SNP) | VAF 88/408 reads (22%) | called by muse, varscan2
- SOX5 | chr12:23950879 A>T | 5'Flank (SNP) | VAF 72/194 reads (37%) | called by muse, mutect2, varscan2
- SSPOP | n.2352G>C | RNA (SNP) | VAF 88/251 reads (35%) | catalogued as COSV50486791; called by muse, mutect2, varscan2
- SYT14 | c.1355-1318C>G | Intron (SNP) | VAF 104/1217 reads (9%) | called by muse, mutect2
- TMPRSS11F | c.1015+1727C>A | Intron (SNP) | VAF 103/371 reads (28%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.269-250G>T | Intron (SNP) | VAF 19/105 reads (18%) | catalogued as rs1215031095; called by muse, mutect2, varscan2
- TSPAN7 | c.82-10102G>A | Intron (SNP) | VAF 21/158 reads (13%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.*147G>A | 3'UTR (SNP) | VAF 55/415 reads (13%) | called by muse, mutect2, varscan2
- XIAP | c.*1502C>G | 3'UTR (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2
- ZNF445 | c.429+36C>T | Intron (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
